Somatic mutation profile of tumor specimen TCGA-VN-A88N-01A (aliquot TCGA-VN-A88N-01A-11D-A364-08) from TCGA case TCGA-VN-A88N, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 62.1 years (22,695 days).
Specimen TCGA-VN-A88N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0a07ca26-ea69-452d-a203-e1e15ec0a827.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VN-A88N-10B (Blood Derived Normal), aliquot TCGA-VN-A88N-10B-01D-A362-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1fbf4ab-1421-4520-9e7b-ba3968dfe7be

The open-access MAF lists 17 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 14, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 28/86 reads (33%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALDOC | c.110T>C p.V37A | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV99256663; called by muse, mutect2, varscan2
- CCBE1 | c.548A>G p.D183G | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.34); PolyPhen benign (0.025); catalogued as rs1200030940, COSV101232781; called by mutect2, varscan2
- CCDC40 | c.2494C>G p.H832D | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV100884233, COSV100884244; called by muse, mutect2, varscan2
- CRB1 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs62635651, CM992147, COSV66339198; ClinVar: not provided; called by muse, mutect2, varscan2
- FGFR1 | c.2002G>A p.A668T (on ENST00000447712 / NM_023110.3; = p.A666T on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58333663; called by muse, mutect2
- GPR158 | c.2474G>A p.R825K | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.813); catalogued as rs1432723451, COSV100892935; called by muse, mutect2, varscan2
- IL1RAPL2 | c.976C>A p.L326M | Missense Mutation (SNP) | VAF 52/73 reads (71%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as COSV100780794; called by muse, mutect2, varscan2
- LAMC1 | c.2464G>A p.V822M | Missense Mutation (SNP) | VAF 38/106 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.296); catalogued as COSV99279096; called by muse, mutect2, varscan2
- NECTIN2 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99374796; called by muse, mutect2, varscan2
- PTGIR | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs756436997, COSV99354903; called by muse, mutect2, varscan2
- RYR3 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs776257846, COSV66793170; called by muse, mutect2, varscan2
- SON | c.2506T>G p.L836V | Missense Mutation (SNP) | VAF 89/268 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV99277072; called by muse, varscan2
- TRIM51 | c.893G>C p.S298T | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV99792208; called by muse, varscan2
- BCOR | c.2320_2329del p.K774Qfs*9 | Frame Shift Del (DEL) | VAF 70/125 reads (56%) | called by mutect2, pindel, varscan2
- CACNA1C | c.720C>T p.R240= | Silent (SNP) | VAF 23/276 reads (8%) | catalogued as rs527755968, COSV100216019; ClinVar: likely benign; called by muse, mutect2
- RP1 | c.4335T>A p.S1445= | Silent (SNP) | VAF 25/79 reads (32%) | catalogued as COSV99606438; called by muse, mutect2, varscan2
